Somatic mutation profile of tumor specimen TCGA-A2-A25F-01A (aliquot TCGA-A2-A25F-01A-11D-A167-09) from TCGA case TCGA-A2-A25F, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.6 years (24,319 days).
Specimen TCGA-A2-A25F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b4c158c-c617-43b6-9d77-43d0d2f1064f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A25F-10A (Blood Derived Normal), aliquot TCGA-A2-A25F-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fbe34fd-cea9-4d4e-90f3-2f7afc54c5c6

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SEL1L3 | c.1696T>A p.C566S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99339878; called by muse, mutect2
- KLK5 | c.450C>T p.H150= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV60451803; called by muse, mutect2, varscan2
